Somatic mutation profile of tumor specimen MBCProject_0399_T1_WES (aliquot MBCProject_0399_T1_WES_1) from CMI case MBCProject_0399, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 46.2 years (16,871 days).
Specimen MBCProject_0399_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b22ec798-8164-4bb8-800f-bdcc10c1bb1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0399_SALIVA (Saliva), aliquot MBCProject_0399_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ad49090-a14c-4999-8e67-83ab39e96ef3

The open-access MAF lists 41 somatic variants for this specimen: 18 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 14, Intron 4, 5'UTR 3, Nonsense Mutation 1, Splice Region 1, 5'Flank 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 33/128 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTN2 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781559530, COSV63971955; called by muse, mutect2, varscan2
- ENAM | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as rs375013075; called by muse, mutect2, varscan2
- HTR2A | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs776251555; called by muse, mutect2, varscan2
- INSYN2A | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs756966142, COSV54753402; called by muse, mutect2, varscan2
- RLN2 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV57731906; called by muse, mutect2, varscan2
- CELSR1 | c.4921G>A p.G1641S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- CYFIP1 | c.2098G>A p.D700N | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDI1 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- GSR | c.970C>G p.P324A | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP4K3 | c.1363A>C p.N455H | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- MTREX | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PDE10A | c.174G>T p.K58N | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PELP1 | c.978C>G p.L326= | Splice Region (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- SATL1 | c.1279dup p.Y427Lfs*19 (on ENST00000395409; = p.Y614Lfs*14 on NM_001012980.2) | Frame Shift Ins (INS) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- SPTAN1 | c.3703G>A p.V1235I | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, mutect2
- THBS2 | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- TTN | c.80856T>A p.N26952K (on ENST00000591111; = p.N19528K on NM_003319.4) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | PolyPhen benign (0.242); called by muse, mutect2, varscan2
- CAPN15 | c.1431C>T p.I477= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs746946764; called by muse, mutect2, varscan2
- CEP55 | c.114G>A p.K38= | Silent (SNP) | VAF 37/124 reads (30%) | called by muse, varscan2
- CTSL | c.99G>A p.K33= | Silent (SNP) | VAF 46/159 reads (29%) | called by muse, mutect2, varscan2
- CYP2C8 | c.1218C>T p.I406= | Silent (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- DIO2 | c.43C>T p.L15= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV70444962; called by muse, varscan2
- DUSP4 | c.609C>G p.L203= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as rs767767045; called by muse, mutect2, varscan2
- EFCAB8 | c.1995C>T p.T665= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as rs539746872; called by muse, mutect2, varscan2
- GOSR2 | c.423C>T p.L141= (on ENST00000393456 / NM_001321134.1; = p.L206= on NM_004287.5) | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as rs756931321; called by muse, mutect2, varscan2
- KIF3B | c.657C>T p.F219= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs1301303416, COSV65227137; called by muse, mutect2, varscan2
- LPIN3 | c.2397G>A p.K799= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs909844447, COSV60035657; called by mutect2, varscan2
- NINL | c.2025G>A p.Q675= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- NOX1 | c.1485C>T p.I495= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV54194259, COSV99471559; called by muse, varscan2
- PROM1 | c.906C>T p.L302= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as COSV71699668; called by muse, mutect2, varscan2
- ZZZ3 | c.1275A>G p.Q425= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as rs575973677; called by muse, mutect2, varscan2
- AC022148.1 | n.258C>T | RNA (SNP) | VAF 13/31 reads (42%) | catalogued as rs1443343672; called by muse, mutect2, varscan2
- ACTG1 | chr17:81512797 G>A | 5'Flank (SNP) | VAF 20/58 reads (34%) | catalogued as rs1371743667; called by muse, mutect2, varscan2
- AP1G2 | c.-60G>A | 5'UTR (SNP) | VAF 7/39 reads (18%) | catalogued as rs979322732, COSV58113041; called by muse, mutect2, varscan2
- CDC5L | c.-31C>T | 5'UTR (SNP) | VAF 65/277 reads (23%) | catalogued as rs759264216; called by muse, mutect2, varscan2
- COL6A1 | c.1741-26G>A | Intron (SNP) | VAF 12/69 reads (17%) | called by mutect2, varscan2
- PRPF6 | c.-35T>A | 5'UTR (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
- SYNE1 | c.4311-12G>A | Intron (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- UCKL1 | c.113+46C>A | Intron (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- VCP | c.1483-18C>G | Intron (SNP) | VAF 30/162 reads (19%) | called by muse, mutect2, varscan2
